Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AAD5, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AAD5-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3

Carcinoma, hepatocellular NOS
8170/3

Site: Liver C22.0
JW 5/19/14

CLINICAL DIAGNOSIS: Hepatocellular carcinoma

Specimen : Liver

Gross Photo :

GROSS:

Specimen:

Liver: 27.0 x 20.0 x 12.0 cm, 3080.0 gm (fresh)

Gallbladder: 9.5 cm in length, 3.5 cm in diameter,
0.2 cm in wall thickness (fresh)

Operation:

Lobectomy, right lobe

Cholecystectomy

[1] Liver

Lesion: A well-defined, round to oval, bile-tinged mass

Size: 16.5 x 14.0 x 11.0 cm

Cut surface: Greenish brown, solid and granular with necrosis (60 %)

Gross type

HCC: Vaguely nodular

Resection margin

Not involved grossly (safety margin: 0.3 cm)

Others:

Satellite nodule: No

Remaining parenchyma: Insufficient for cirrhotic features

Portal vein invasion: No

[2] Gallbladder

Mucosal surface: Greenish yellow and velvety

Serosal surface: Brown and smooth

Representative sections are submitted.

Gross photo: Present

Blocks

T1-4, bile tinged mass and surrounding liver parenchyme x 4

L, nontumorous liver parenchyme x 1

RM, resection margin of liver x 1

GB, gallbladder and cystic duct resection margin x 1

MICROSCOPIC:

Hepatocellular carcinoma:

The worst differentiation III

The major differentiation III

[page 2 of 2]
Histologic type: Trabecular
Cell type: Hepatic
Fatty change: No
Fibrous capsule formation: Partial capsule
Capsular infiltration: Yes
Septum formation: No
Surgical resection margin invasion: No
Serosal invasion: No
Portal vein invasion: No
Microvessel invasion: No
Intrahepatic metastasis: No
Multicentric occurrence: No

Non-tumor liver pathology

Chronic hepatitis:
Etiology: HBV
Grade, lobular: Minimal
Grade, portoperiportal: Minimal
Stage (fibrosis): Septal
Dysplastic nodule: No
Ductal epithelial dysplasia: No
Other liver diseases: No

NOT reported. Gross:

NOT reported. Gross:

Liver, ectomy, hepatocellular carcinoma
T56000, P10, M81703
Gallbladder, ectomy, chronic cholecystitis
T57000, P10, M43005

DIAGNOSIS:

Liver, right, lobectomy: Hepatocellular carcinoma

Gallbladder, cholecystectomy: Chronic cholecystitis

Suggestion :

Source: NCI Genomic Data Commons file 8368cfb5-c71a-4ec7-93d3-1ae0d181e1ab (TCGA-DD-AAD5.7F74E08A-C14B-413E-9D75-FCDBFC2F67C5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).